Somatic mutation profile of tumor specimen TCGA-EL-A3H3-01A (aliquot TCGA-EL-A3H3-01A-11D-A202-08) from TCGA case TCGA-EL-A3H3, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 19.2 years (7,000 days).
Specimen TCGA-EL-A3H3-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c079fb3c-cd64-411a-98ca-665ceecab718.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3H3-10A (Blood Derived Normal), aliquot TCGA-EL-A3H3-10A-01D-A202-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45e520d2-7be0-4859-9814-ae024675988b

The open-access MAF lists 2 somatic variants for this specimen: 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Silent 1, 5'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PLPP6 | c.363G>C p.A121= | Silent (SNP) | VAF 16/52 reads (31%) | catalogued as COSV56304453, COSV56306439; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503978 ins A | 5'Flank (INS) | VAF 4/17 reads (24%) | called by mutect2, pindel, varscan2
